Somatic mutation profile of tumor specimen TARGET-40-PAKZZK-01A (aliquot TARGET-40-PAKZZK-01A-01Y) from TARGET case TARGET-40-PAKZZK, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.3 years (4,864 days).
Specimen TARGET-40-PAKZZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92f8b95d-aa31-47e4-98b2-33bde39ee039.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAKZZK-10A (Blood Derived Normal), aliquot TARGET-40-PAKZZK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c3f4283-f60d-45ca-b5e0-b241ffbf1347

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Ins 4, Silent 4, Intron 3, Frame Shift Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 30/46 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B2 | c.2336G>A p.R779H (on ENST00000352432; = p.R745H on NM_001683.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280783124, COSV100659922, COSV59497574; called by mutect2, varscan2
- CCDC58 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as rs748569885; called by muse, mutect2, varscan2
- COBL | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as COSV54342694; called by muse, mutect2, varscan2
- H2AC1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.118); catalogued as rs775985152, COSV99219384; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | catalogued as rs780916980; called by mutect2, varscan2
- PASK | c.1811dup p.S605Qfs*12 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs769655744; called by pindel, varscan2
- TRRAP | c.4856dup p.A1620Cfs*35 (on ENST00000359863 / NM_001244580.1; = p.A1602Cfs*35 on NM_003496.3) | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs781980072; called by pindel, varscan2
- ZC3H3 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs777365051; called by muse, mutect2, varscan2
- CFI | c.1656A>T p.K552N | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DNAH3 | c.4201dup p.R1401Pfs*48 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | called by pindel, varscan2
- HECTD1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- HSH2D | c.295del p.H99Tfs*23 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- LPIN1 | c.1239_1250+4del p.X413_splice | Splice Site (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- NLRP14 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA2 | c.1720_1727del p.N574Pfs*11 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- PTH2R | c.1591A>T p.R531W | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- AKAP8L | c.1098G>A p.Q366= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- DDX39A | c.1131G>A p.A377= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs375502494; called by muse, mutect2, varscan2
- IFNAR1 | c.1245G>C p.L415= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV54251308; called by muse, mutect2, varscan2
- TMEM50B | c.273A>G p.G91= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- FEZ2 | c.904-37C>A | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
- POLR1E | chr9:37486091 G>A | 5'Flank (SNP) | VAF 3/10 reads (30%) | catalogued as rs1199482677; called by muse, varscan2
- RPL4 | c.283-130T>A | Intron (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- ZMYM6 | c.428+120T>C | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
